Somatic mutation profile of tumor specimen MP2PRT-PAVVLH-TMP1-B (aliquot MP2PRT-PAVVLH-TMP1-B-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVVLH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,044 days).
Specimen MP2PRT-PAVVLH-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f796cdc3-ad78-4db0-9efc-49559a9eaf8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVVLH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVVLH-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb3aa33b-2e96-445c-bf5d-0a7d40a6e9d8

The open-access MAF lists 48 somatic variants for this specimen: 32 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 12, Nonsense Mutation 2, 3'Flank 2, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP4A | c.2851C>T p.R951C | Missense Mutation (SNP) | VAF 74/441 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769093964; called by muse, mutect2, varscan2
- BSDC1 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 29/451 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.834); catalogued as rs561306235; called by muse, mutect2
- CUX2 | c.2516C>T p.A839V | Missense Mutation (SNP) | VAF 194/848 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1465916018, COSV55642933; called by muse, mutect2, varscan2
- FIGN | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 19/664 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1205155374, COSV60769455, COSV60772025; called by muse, mutect2
- HS1BP3 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 56/313 reads (18%) | catalogued as rs750241786, COSV100397957; called by muse, mutect2, varscan2
- HTR4 | c.540C>A p.N180K | Missense Mutation (SNP) | VAF 65/338 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.974); catalogued as rs1561587164; called by muse, mutect2, varscan2
- IFIH1 | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 88/421 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV99718453; called by muse, mutect2, varscan2
- INSRR | c.3250C>A p.L1084I | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs749935027; called by muse, mutect2, varscan2
- KDR | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 85/485 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.352); catalogued as rs374980446; called by muse, mutect2, varscan2
- LINGO2 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 86/500 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as rs866067533, COSV58064896; called by muse, mutect2, varscan2
- PAPSS1 | c.1624G>A p.G542S | Missense Mutation (SNP) | VAF 28/486 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99492494; called by muse, mutect2
- PNMA2 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 56/327 reads (17%) | catalogued as COSV101580614; called by muse, mutect2, varscan2
- SIGLEC1 | c.2624G>A p.R875H | Missense Mutation (SNP) | VAF 106/462 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.049); catalogued as rs771835174, COSV52471375; called by muse, mutect2, varscan2
- ZNF804A | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 36/476 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.265); catalogued as rs866891873, COSV56458660; called by muse, mutect2
- ADAM7 | c.330A>T p.Q110H | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHI1 | c.2516G>A p.G839E | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DYNC1I1 | c.307G>C p.V103L | Missense Mutation (SNP) | VAF 25/428 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2
- ELFN1 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 156/775 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.007); called by muse, varscan2
- FBXO17 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 33/654 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.675); called by muse, mutect2
- FLNC | c.3275C>G p.T1092R | Missense Mutation (SNP) | VAF 64/619 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.821); called by muse, mutect2
- HABP2 | c.854A>G p.E285G | Missense Mutation (SNP) | VAF 98/406 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- HDAC8 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.223); called by muse, mutect2
- IGHV3-66 | chr14:106675015 TCTCTC>GGGAGG | Missense Mutation (ONP) | VAF 57/164 reads (35%) | called by pindel, varscan2*
- IGHV5-51 | chr14:106578742 TGTCTCGCAC>CCTCGG | Missense Mutation (DEL) | VAF 43/97 reads (44%) | called by pindel, varscan2*
- IPO13 | c.1858C>A p.Q620K | Missense Mutation (SNP) | VAF 43/302 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- LGI2 | c.495G>T p.R165S | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NEBL | c.1852C>G p.Q618E | Missense Mutation (SNP) | VAF 11/283 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NUMB | c.1738G>T p.A580S (on ENST00000355058; = p.A569S on NM_003744.5) | Missense Mutation (SNP) | VAF 47/428 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- OR8B3 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.167); called by muse, mutect2
- PKD1 | c.1940G>T p.C647F | Missense Mutation (SNP) | VAF 128/851 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PRKACA | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAB40A | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 162/354 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CXCL8 | c.156G>C p.L52= | Silent (SNP) | VAF 38/460 reads (8%) | catalogued as rs1366295314; called by muse, mutect2
- KRT33B | c.978G>A p.A326= | Silent (SNP) | VAF 167/774 reads (22%) | catalogued as rs112724807; called by muse, mutect2, varscan2
- LAMB4 | c.1995G>A p.A665= | Silent (SNP) | VAF 51/322 reads (16%) | catalogued as rs533527693, COSV99222823; called by muse, mutect2, varscan2
- MROH6 | c.2025G>A p.R675= | Silent (SNP) | VAF 146/997 reads (15%) | called by muse, mutect2
- MYO15A | c.1758C>T p.I586= | Silent (SNP) | VAF 158/683 reads (23%) | catalogued as rs990279319; called by muse, mutect2, varscan2
- PHYKPL | c.579G>A p.V193= | Silent (SNP) | VAF 39/383 reads (10%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.10131G>A p.G3377= | Silent (SNP) | VAF 18/372 reads (5%) | called by muse, mutect2
- RAD21 | c.177C>G p.L59= | Silent (SNP) | VAF 40/332 reads (12%) | called by muse, mutect2, varscan2
- SBNO2 | c.4011G>A p.A1337= | Silent (SNP) | VAF 50/654 reads (8%) | catalogued as rs771138025; called by muse, mutect2
- SLC17A6 | c.681G>A p.V227= | Silent (SNP) | VAF 21/339 reads (6%) | called by muse, mutect2
- SORBS1 | c.1191T>C p.T397= (on ENST00000361941 / NM_001034954.2; = p.T233= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 73/372 reads (20%) | called by muse, mutect2, varscan2
- TACC1 | c.876A>G p.K292= | Silent (SNP) | VAF 80/382 reads (21%) | called by muse, mutect2, varscan2
- COL1A2 | chr7:94392157 C>T | 5'Flank (SNP) | VAF 22/340 reads (6%) | called by muse, mutect2
- IGHV1-69 | chr14:106714683 ins GGG | 3'Flank (INS) | VAF 22/43 reads (51%) | called by mutect2, pindel*, varscan2*
- IGLV4-69 | chr22:22031472 ins TCCT | 3'Flank (INS) | VAF 38/175 reads (22%) | called by mutect2, pindel, varscan2
- SHTN1 | c.1359+233A>T | Intron (SNP) | VAF 19/436 reads (4%) | called by muse, mutect2
